Gene-level copy-number profile of tumor specimen ALCH-B1QB-TTP1-A from ALCHEMIST case ALCH-B1QB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.7 years (24,720 days).
Specimen ALCH-B1QB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7f7edfa6-fc63-47af-9cbf-f2cbdf21990e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1QB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/92cd80ac-9db6-4ff1-8501-920d34feb4a5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 3,160; copy number 2: 49,046; copy number 3: 5,127; copy number 4: 726; copy number 5: 238; copy number 6: 2; copy number 7: 5; copy number 8: 68.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,159,840–90,160,335, 1 gene (within-gene range 0–1): IGKV1D-12.
- chr2:90,309,230–90,315,836, 2 genes: AC233263.2, IGKV1OR2-118.
- chr10:42,209,990–42,210,383, 1 gene: AL031601.1.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:89,873,570–89,913,627, 1 gene (within-gene range 0–1): TCF25.
- chr16:89,912,119–89,920,973, 1 gene (within-gene range 0–1): MC1R.
- chr21:10,482,738–13,067,033, 9 genes (within-gene range 0–1): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.
- chr22:43,038,585–43,092,524, 3 genes: TTLL1-AS1, TTLL1, AL022237.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 313 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:102,763,322–104,226,678, 18 genes, copy number 5: AC099567.1, COL11A1, SOD2P1, AC095032.2, AC095032.1, RN7SKP285, RNPC3, AMY2B, ACTG1P4, AMY2A, AMY1A, AC105272.1, AMY1B, AMYP1, AMY1C, AL136455.1, AC092506.1, FTLP17.
- chr5:58,198–2,262,023, 76 genes, copy number 5 (broad region; genes not listed).
- chr7:54,185,071–57,837,046, 142 genes, copy number 5–8 (broad region; genes not listed).
- chr16:7,726,841–11,182,186, 74 genes, copy number 5 (broad region; genes not listed).
- chr17:46,503,946–46,555,650, 3 genes, copy number 6–8: RDM1P2, LRRC37A2, RN7SL199P.

Autosomal genes at a single copy (total copy number 1): 855. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
